Surgical pathology report (de-identified scan), TCGA case TCGA-21-1078, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-21-1078-01A (Primary Tumor).

[page 1 of 5]
Clinical History/Diagnosis: Right Lung Cancer

Source of Specimen(s):

- 1: Pleural biopsy
- 2: Pleural biopsy #2
- 3: Sixth rib
- 4: Level 9 lymph nodes
- 5: Level 7 lymph nodes
- 6: Level 11 lymph nodes
- 7: RLL
- 8: 10R lymph nodes
- 9: 4R lymph nodes
- 10: 2R lymph nodes
- 11: New bronchial margin

Gross Description:

Received in eleven parts.

Source of Tissue: 1. Labeled #1, "right pleural biopsy"

Frozen Section Diagnosis: 1FS- FIBROUS PLAQUE.

Gross Description: Received fresh for frozen section evaluation labeled [REDACTED], right pleural biopsy" are four white-tan firm tissue fragments, 1.5 cm in greatest dimension. They are entirely submitted for frozen section evaluation and the frozen itself is submitted in one block.

Designation of Sections: 1FS

Summary of Sections: FS-multiple

Source of Tissue: 2. Labeled #2, "pleural biopsy #2"

Frozen Section Diagnosis: 2FS- FIBROUS PLAQUE.

Gross Description: Received fresh for frozen section evaluation labeled "[REDACTED], pleural biopsy #2" is a 0.6 cm white-tan firm tissue fragment. It is submitted in toto for frozen section evaluation and the frozen itself is submitted in one block.

Designation of Sections: 2FS

Summary of Sections: FS-1

[page 2 of 5]
Source of Tissue: 3. Labeled #3, "sixth rib"

Gross Description: Received fresh labeled "[REDACTED]" and "[REDACTED]" sixth rib" are two tan to red-purple fragments of rib, 1.5 and 5.5 cm in greatest dimension. Each has a minimal amount of attached soft tissue. Representative sections are submitted in two blocks.

Designation of Sections: 3A-3B

Summary of Sections: multiple

Source of Tissue: 4. Labeled #4, "level 9"

Gross Description: Received fresh labeled "[REDACTED]" and "[REDACTED]", level 9" are two yellow-tan anthracotic stained tissue fragments, 0.4 and 1.2 cm in greatest dimension. They are submitted in toto in one block.

Designation of Sections: Block 4

Summary of Sections: undesignated-2

Source of Tissue: 5. Labeled #5, "level 7"

Gross Description: Received fresh labeled "[REDACTED]" and "[REDACTED]", level 7" are 1.5 x 1.0 x 0.6 cm of red-brown anthracotic stained tissue fragments. They are submitted in toto in one block.

Designation of Sections: Block 5

Summary of Sections: undesignated-multiple

Source of Tissue: 6. Labeled #6, "level 11"

Gross Description: Received fresh labeled "[REDACTED]" and "[REDACTED]", level 11" are 1.0 x 0.6 x 0.3 cm of tan to gray-black anthracotic stained tissue fragments. They are submitted in toto in one block.

Designation of Sections: Block 6

Summary of Sections: undesignated-multiple

Source of Tissue: 7. Labeled #7, "right LL"

[page 3 of 5]
Frozen Section Diagnosis: 7FS- IN SITU CARCINOMA AT MARGIN.

Gross Description: Received fresh for frozen section evaluation labeled " [REDACTED] and [REDACTED], right LL" is a 327 gram, 18.0 x 13.5 x 3.5 cm right lower lobectomy of lung. It is covered by a pink to red-purple focally anthracotic stained pleura. In the apical aspect there is an overlying, 15.5 x 6.0 cm pink-red fragment of parietal pleura. There is up to 1.0 cm of attached bronchus. The bronchial resection margin is submitted for frozen section evaluation and the frozen section residue is submitted in one block. The lung is sectioned to reveal tan-pink to red-purple soft glistening lung parenchyma. In the superior segment in the area of the overlying parietal pleura there is a 6.5 x 5.0 x 3.0 cm mass having tan to red-purple focally firm predominantly necrotic cut surfaces. In the basal aspect there is a second, 7.5 x 5.0 x 4.0 cm mass having tan firm cut surfaces. There are several palpable peribronchial lymph nodes, 0.6 cm in greatest dimension. The cut surface of each is gray-black and anthracotic stained. Representative sections are submitted in nine blocks.

Designation of Sections: 7FS- frozen section bronchial resection margin, 7A- vascular margins, 7B-7D- superior mass, 7E-7G- basal mass, 7H- random lung sections, 7I- peribronchial lymph nodes

Summary of Sections: multiple

Source of Tissue: 8. Labeled #8, "10R nodes"

Gross Description: Received fresh labeled " [REDACTED] and [REDACTED], 10R nodes" are two gray-black anthracotic stained tissue fragments, 0.6 cm in greatest dimension. They are submitted in toto in one block.

Designation of Sections: Block 8

Summary of Sections: undesignated-2

Source of Tissue: 9. Labeled #9, "4R lymph nodes"

Gross Description: Received fresh labeled " [REDACTED] and [REDACTED], 4R lymph nodes" is a 1.5 x 1.0 x 0.5 cm yellow-tan to gray-black anthracotic stained tissue fragment. It is entirely submitted in two blocks.

Designation of Sections: 9A-9B

Summary of Sections: multiple

Source of Tissue: 10. Labeled #10, "2R lymph node"

[page 4 of 5]
Gross Description: Received fresh labeled " [REDACTED] and [REDACTED] #, 2R lymph node" are 1.5 x 1.0 x 0.4 cm of yellow-tan focally anthracotic stained tissue fragments. They are submitted in toto in one block.

Designation of Sections: Block 10

Summary of Sections: undesignated-multiple

Source of Tissue: 11. Labeled #11, "new bronchial margin"

Frozen Section Diagnosis: 11FS- NO TUMOR SEEN PER.

Gross Description: Received fresh for frozen section evaluation labeled " [REDACTED] and [REDACTED], new bronchial margin" is a 1.5 x 0.4 cm tan fragment of cartilage having a suture marking the proximal end. The opposite margin has multiple staples. The staples are removed, the remaining tissue is entirely submitted for frozen section evaluation and the frozen itself is submitted in one block.

Designation of Sections: 11FS

Summary of Sections: FS-multiple

Final Diagnosis:

1. Pleura, biopsy:- Fibrous plaque, no tumor seen.
2. Pleural biopsy #2:
- Fibrous plaque, no tumor seen.
3. 6th rib, resection:- Bone and bone marrow with trilineage hematopoiesis.
4. Level 9 lymph node, excision:- Two lymph nodes, no tumor seen (0/2).
5. Level 7 lymph nodes, excision:- Seven lymph nodes, no tumor seen (0/7).
6. Level 11 lymph nodes, excision:- Two lymph nodes, no tumor seen (0/2).
7. Right lung, lower lobe, lobectomy:
- Multifocal invasive moderately differentiated non-keratinizing squamous cell carcinoma (6.5 cm and 7.5 cm); one of which (6.5 cm) shows invasion of the visceral pleura with adhesion of parietal pleura; definitive lymphovascular invasion not seen, see note.
- Bronchial margin of the specimen shows squamous metaplasia with severe dysplasia/carcinoma in situ (best seen on the frozen section).
- Vascular resection margin with no tumor seen.

[page 5 of 5]
- Six peribronchial lymph nodes with no tumor seen (0/6).

Note: For staging, the two tumors may represent synchronous primaries and each staged as pT2N0Mx. Alternatively, one may represent an intrapulmonary metastasis (would be staged as pT4N0Mx). Selected slides have been reviewed with [REDACTED] who concurs in the diagnosis.

8. 10R lymph nodes, excision:- Two lymph nodes, no tumor seen (0/2).

9. 4R lymph nodes, excision:- One lymph node, no tumor seen (0/1).

10. 2R lymph node, excision:- Two lymph nodes, no tumor seen (0/2).

11. New bronchial margin, resection:- Bronchial wall with focal squamous metaplasia with atypia.

Source: NCI Genomic Data Commons file 9d7e302f-7d49-4fd1-bea0-2486115c2c1e (TCGA-21-1078.8366DF03-5B00-4476-9FD2-3BF80D53DC6E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).